Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A7NR, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A7NR-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: LIVER, NODULE, EXCISION -

- A. NO VIABLE TUMOR CELLS SEEN.
- B. DEGENERATED/NECROTIC NODULE WITH HEMORRHAGE AND FIBRINOUS DEBRIS.

PART 2: ESOPHAGUS AND STOMACH AND JEJUNUM, ESOPHAGOGASTRECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, MEASURING 2.5 CM, INVOLVING GASTROESOPHAGEAL JUNCTION.
- B. TUMOR INVADES INTO ADVENTITIAL SOFT TISSUES.
- C. ALL SURGICAL MARGINS (PROXIMAL, DISTAL AND RADIAL) ARE FREE OF TUMOR.
- D. EXTENSIVE LYMPHOVASCULAR SPACE PERMEATION PRESENT.
- E. PERINEURAL INVASION PRESENT.
- F. METASTATIC ADENOCARCINOMA INVOLVING NINE (9) OF SEVENTEEN (17) REGIONAL LYMPH NODES WITH EXTRACAPSULAR EXTENSION.
- G. FOCAL SUTURE GRANULOMA.
- H. AJCC PATHOLOGIC TUMOR STAGE: pT3 N3 M1

PART 3: LYMPH NODE, JEJUNAL MESENTERIC, BIOPSY -

METASTATIC ADENOCARCINOMA INVOLVING ONE (1) OF ONE (1) LYMPH NODE.

PART 4: POSSIBLE JEJUNAL MESENTERY, EXCISION -

METASTATIC ADENOCARCINOMA INVOLVING SEVEN (7) OF SEVEN (7) LYMPH NODES.

PART 5: PROXIMAL SMALL BOWEL, RESECTION -

BENIGN SMALL INTESTINAL TISSUE.

PART 6: SMALL BOWEL, RESECTION -

BENIGN SMALL INTESTINAL TISSUE.

PART 7: FINAL ANASTOMOSIS, EXCISION -

BENIGN ESOPHAGEAL AND SMALL INTESTINAL TISSUE.

PART 8: HERNIA SAC, EXCISION -

HERNIA SAC.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: JE junction C16.0
9/24/13

COMMENT:

Part 1: AFB, PAS and silver stains are negative for acid fast and fungal organisms.

Parts 1&2: reviewed select slides and agrees with the interpretation.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Esophagogastric junction (EGJ) region (tumor involves EGJ and epicenter within 5cm of EGJ)
TUMOR SIZE: Greatest dimension: 2.5 cm
Additional dimensions: 1.6 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3
PATHOLOGIC STAGING (pTNM)
pT3
pN3
Number of lymph nodes examined: 17
Number of lymph nodes involved: 9
17 or more regional lymph nodes were identified
pM1
Specify site(s): Jejunal mesenteric lymph nodes.
Treatment history not known

PRIOR TREATMENT:
MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Present

ANGIOLYMPHATIC INVASION:

ADDITIONAL PATHOLOGIC FINDINGS: None identified

Diagnosis Discrepancy	hw 8/20/13	

Source: NCI Genomic Data Commons file 55b6f2bc-6c70-4b57-8dcf-55f84751915c (TCGA-IN-A7NR.B2AEEABA-EBD1-40E2-B3DD-C7C566C4D8B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).